TARGET case TARGET-10-SJBALL004182 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/ba6f3718-3fad-4dd9-af20-1b48832e4db7

Biospecimens (4 samples)
- Samples TARGET-10-SJBALL004182-09A, TARGET-10-SJBALL004182-09A.1, TARGET-10-SJBALL004182-09A.2, TARGET-10-SJBALL004182-09A.3 (4 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
